Somatic mutation profile of tumor specimen TCGA-68-7757-01B (aliquot TCGA-68-7757-01B-11D-2293-08) from TCGA case TCGA-68-7757, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.7 years (27,272 days).
Specimen TCGA-68-7757-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650ffcd1-7602-4c21-a943-ec56d866c33a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-7757-10A (Blood Derived Normal), aliquot TCGA-68-7757-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abca5353-a1cb-406e-bba1-b8ec1819c890

The open-access MAF lists 333 somatic variants for this specimen: 264 protein-altering or splice-affecting, 65 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 65, Nonsense Mutation 18, Splice Site 6, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, RNA 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 23/171 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99227293; called by muse, mutect2
- ADAM18 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.778); catalogued as COSV55847340, COSV99696272; called by muse, mutect2, varscan2
- ADAMTS19 | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184673; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1856G>C p.C619S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99445559; called by muse, mutect2, varscan2
- ADCK1 | c.376A>T p.S126C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99452976; called by muse, mutect2, varscan2
- AHDC1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899869; called by muse, mutect2
- AHR | c.1885C>A p.Q629K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as COSV99620422; called by muse, mutect2, varscan2
- ANK2 | c.6218T>C p.I2073T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1421884505, COSV100004865; called by muse, mutect2, varscan2
- ARC | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100751809; called by muse, mutect2
- ASH2L | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs762558111, COSV99167064; called by muse, mutect2, varscan2
- ASTN1 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99923624; called by muse, mutect2
- ATP10D | c.3214G>T p.G1072W | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99906339; called by muse, mutect2, varscan2
- ATP6V0D1 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99341419; called by muse, mutect2, varscan2
- ATP6V1B2 | c.604-2A>G p.X202_splice | Splice Site (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99369529, COSV99369650; called by muse, mutect2
- ATRAID | c.267A>G p.I89M (on ENST00000611786; = p.I34M on NM_001170795.3) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99256117; called by muse, mutect2
- ATRX | c.5540A>G p.Y1847C | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002235, COSV100971685; called by muse, mutect2, varscan2
- AVEN | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.164); catalogued as COSV100145969; called by muse, mutect2, varscan2
- AVL9 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.149); catalogued as COSV100594858; called by muse, mutect2, varscan2
- AVPR1B | c.1037T>C p.L346S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs782002209, COSV100899487; called by mutect2, varscan2
- BCAR1 | c.2127G>T p.Q709H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99367698; called by muse, mutect2, varscan2
- BEND7 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100347138; called by muse, mutect2, varscan2
- BNIP5 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV101465246; called by muse, mutect2, varscan2
- C8A | c.369T>A p.D123E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376825198; called by muse, mutect2, varscan2
- C8A | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100776707, COSV63483419; called by muse, mutect2, varscan2
- CACNA1I | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs769561916, COSV60800640; called by muse, mutect2, varscan2
- CACNA2D1 | c.2264A>T p.N755I (on ENST00000356253 / NM_001366867.1; = p.N743I on NM_000722.4) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV100667700, COSV62386720; called by muse, mutect2, varscan2
- CAND1 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101607367; called by muse, mutect2, varscan2
- CD163 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100776225; called by muse, mutect2, varscan2
- CHRD | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs371620797; called by muse, mutect2, varscan2
- COL1A2 | c.280-1G>T p.X94_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV99801670; called by muse, mutect2, varscan2
- COL1A2 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99801674; called by muse, mutect2, varscan2
- COQ10B | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs745644906, COSV99827507; called by muse, mutect2, varscan2
- CPA3 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56046187; called by muse, mutect2, varscan2
- CPNE7 | c.1592C>A p.A531D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334495569, COSV99255243; called by muse, mutect2, varscan2
- CPS1 | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244528; called by muse, mutect2, varscan2
- CTNNA2 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV100786797; called by muse, mutect2, varscan2
- DBNDD2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619523, COSV100619635; called by muse, mutect2, varscan2
- DCC | c.3395A>C p.K1132T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101473680; called by muse, mutect2, varscan2
- DEFB106A | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs767005789, COSV100068759; called by mutect2, varscan2
- DEFB113 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101290424, COSV101290425; called by muse, mutect2, varscan2
- DENND4C | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs753820235, COSV100991595; called by muse, mutect2, varscan2
- DGKA | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100093611; called by mutect2, varscan2
- DGKG | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as COSV99404723; called by muse, mutect2, varscan2
- DNAAF3 | c.1067C>T p.S356F (on ENST00000524407 / NM_001256715.2; = p.S403F on NM_178837.4) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV100788053; called by muse, mutect2, varscan2
- DSP | c.3710A>T p.N1237I | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101131924; called by muse, mutect2, varscan2
- DST | c.11435A>C p.Q3812P (on ENST00000361203 / NM_001374722.1; = p.Q1400P on NM_015548.5) | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99761245; called by muse, mutect2, varscan2
- DUSP22 | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100740189; called by muse, mutect2, varscan2
- ECHDC1 | c.289A>G p.T97A (on ENST00000531967 / NM_001139510.1; = p.T91A on NM_018479.3) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV100541975; called by muse, mutect2, varscan2
- EEPD1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99633345; called by muse, mutect2, varscan2
- EPHA6 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101066243; called by muse, mutect2, varscan2
- EPHB6 | c.1525T>C p.W509R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100844509; called by muse, mutect2, varscan2
- EPX | c.1580C>A p.A527D | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99836850; called by muse, mutect2, varscan2
- ERBB4 | c.3911G>T p.R1304L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61502134; called by muse, mutect2, varscan2
- FAF1 | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV65642672; called by muse, mutect2, varscan2
- FAM135B | c.3629C>A p.S1210Y | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52746216; called by muse, mutect2, varscan2
- FAM160B2 | c.1966A>T p.R656W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99249369; called by muse, mutect2, varscan2
- FAM89A | c.455A>T p.Q152L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV100792681; called by muse, mutect2, varscan2
- FBLN7 | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99735042; called by muse, mutect2, varscan2
- FBN1 | c.8319C>A p.N2773K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100356702; called by muse, mutect2, varscan2
- FCGR3A | c.289A>G p.S97G | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100914735; called by muse, mutect2
- FGF14 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101084203, COSV65935980; called by muse, mutect2, varscan2
- FLG2 | c.6688A>T p.T2230S | Missense Mutation (SNP) | VAF 96/606 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV101166339; called by muse, mutect2, varscan2
- FMN2 | c.3217G>A p.G1073S | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV100147938; called by muse, mutect2, varscan2
- FOLH1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57054924; called by muse, mutect2, varscan2
- FRMPD1 | c.4718G>T p.R1573L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV66700145; called by muse, mutect2, varscan2
- GABRR1 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567561851, COSV65619752; called by muse, mutect2, varscan2
- GAL3ST3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs750464463, COSV100361060; called by muse, mutect2, varscan2
- GALC | c.1028T>A p.V343E | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99730768; called by muse, mutect2
- GALNT17 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV100356984; called by muse, mutect2, varscan2
- GIGYF2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101004678; called by muse, mutect2, varscan2
- GJC1 | c.130T>G p.Y44D | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395268; called by muse, mutect2, varscan2
- GLRA4 | c.1151C>A p.A384E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs753313587, COSV100129143; called by muse, mutect2, varscan2
- GNAZ | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV50742958, COSV99321355; called by muse, mutect2, varscan2
- GRB14 | c.1241T>G p.L414R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99814695; called by muse, mutect2, varscan2
- GRIPAP1 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs781800766, COSV100904320; called by muse, mutect2, varscan2
- GRM8 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100286986; called by muse, mutect2, varscan2
- GTF2H3 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952938715, COSV99967694; called by muse, mutect2
- H1-2 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59191504, COSV59191681; called by muse, mutect2
- HDC | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV51084975, COSV99983733; called by muse, mutect2
- HDC | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99984018; called by muse, mutect2
- HOXD10 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV50903594, COSV99983086; called by muse, mutect2, varscan2
- HOXD13 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs367674921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYKK | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100856488; called by muse, mutect2, varscan2
- IFNA5 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99423639, COSV99423801; called by muse, mutect2, varscan2
- IFNW1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV101207658; called by muse, mutect2, varscan2
- IFT52 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100887712; called by muse, mutect2, varscan2
- INTS6 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100247314; called by muse, mutect2, varscan2
- IRF6 | c.1003A>C p.N335H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100884050; called by muse, mutect2, varscan2
- ITPRID1 | c.2624A>G p.Q875R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV100087910; called by muse, mutect2, varscan2
- JAK2 | c.2027C>A p.A676D | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101081685; called by muse, mutect2, varscan2
- KCNK12 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100010121; called by muse, mutect2, varscan2
- KIF16B | c.3122G>A p.S1041N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100735036; called by muse, mutect2, varscan2
- KIF1A | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374011613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL28 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.055); catalogued as COSV100753356; called by muse, mutect2
- KLK13 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50066840; called by muse, mutect2, varscan2
- KRT6C | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs199836454; called by muse, mutect2, varscan2
- LATS1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | catalogued as COSV53598599; called by muse, mutect2, varscan2
- LCE1F | c.250A>T p.R84W | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100542812; called by muse, mutect2
- LDB2 | c.502T>A p.L168I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100455261; called by muse, mutect2, varscan2
- LILRA2 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV99254156; called by muse, mutect2, varscan2
- LMLN | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100218991; called by muse, mutect2, varscan2
- LMO4 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV100984012; called by muse, mutect2, varscan2
- LMO7 | c.620G>T p.G207V (on ENST00000357063; = p.G222V on NM_005358.5) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100414024; called by muse, mutect2, varscan2
- LPA | c.3312G>T p.R1104S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1357368052, COSV100308383; called by muse, mutect2, varscan2
- LPA | c.3311G>T p.R1104M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100308384; called by muse, mutect2, varscan2
- LRP1B | c.8681C>G p.S2894* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV67191715, COSV67217271; called by muse, mutect2
- LRP6 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99744887; called by muse, mutect2, varscan2
- LRRC45 | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100142001; called by muse, mutect2, varscan2
- MACF1 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100487282; called by muse, mutect2
- MAGED1 | c.2097G>T p.E699D | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV100431931; called by muse, mutect2, varscan2
- MAN1A2 | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1286855339, COSV100741103; called by muse, mutect2, varscan2
- MAN2B1 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 33/169 reads (20%) | catalogued as COSV99667481; called by muse, mutect2, varscan2
- MANF | c.311A>T p.K104M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99816107; called by muse, varscan2
- MBIP | c.504A>T p.E168D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV100576865; called by muse, mutect2, varscan2
- MCM5 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373130534, COSV99332115; called by muse, mutect2, varscan2
- MDGA2 | c.2323G>A p.E775K (on ENST00000399232 / NM_001113498.2; = p.E477K on NM_182830.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV100638912; called by muse, mutect2, varscan2
- MED26 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99660274; called by muse, mutect2, varscan2
- METTL27 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99936663; called by muse, mutect2
- MFSD1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99964187; called by muse, mutect2
- MGAM | c.4976C>A p.A1659D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101527810, COSV72074781; called by muse, mutect2, varscan2
- MIA2 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV99698380; called by muse, mutect2, varscan2
- MYH2 | c.5160G>C p.Q1720H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55438333, COSV99821250; called by muse, mutect2, varscan2
- MYO16 | c.5115G>A p.M1705I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV62754409; called by muse, mutect2, varscan2
- NBPF1 | c.2570A>T p.H857L | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.885); catalogued as rs1388994250, COSV99845179; called by muse, mutect2, varscan2
- NCAM2 | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99526143; called by mutect2, varscan2
- NCOA1 | c.3790C>T p.Q1264* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99947410; called by muse, mutect2, varscan2
- NOTCH3 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99659367; called by muse, mutect2, varscan2
- NR4A1 | c.1483A>G p.S495G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99671892; called by muse, mutect2
- NSD1 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as CM030068, COSV61770550; called by muse, mutect2, varscan2
- NUMBL | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1346588234, COSV99425195; called by muse, mutect2, varscan2
- NXPE4 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772742540, COSV100970609, COSV64943887; called by muse, mutect2, varscan2
- OPCML | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100106250; called by muse, mutect2
- OPTN | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV99537852; called by mutect2, varscan2
- OR10H2 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs770573030, COSV100008914; called by muse, mutect2, varscan2
- OR10X1 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1026278333, COSV63766956; called by muse, mutect2
- OR11G2 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100640087; called by muse, mutect2, varscan2
- OR2L2 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV100824422, COSV63554652; called by muse, mutect2, varscan2
- OR2T6 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV100861676; called by muse, mutect2, varscan2
- OR4C11 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100155592, COSV56353774; called by muse, mutect2, varscan2
- OR4C46 | c.561C>G p.C187W | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs764223636, COSV100061114; called by muse, mutect2, varscan2
- OR4F15 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767352004, COSV100173978; called by muse, mutect2, varscan2
- OR4K5 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100262719; called by muse, mutect2
- OR51I1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100972256, COSV66507327; called by muse, mutect2, varscan2
- OR52L1 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100176430; called by mutect2, varscan2
- OR5AK2 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1327794212, COSV100476211; called by muse, mutect2, varscan2
- OR5J2 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as rs1188786557, COSV100399339; called by muse, mutect2, varscan2
- OR5M10 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101595936; called by muse, mutect2, varscan2
- OR5T1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100479224, COSV100479288; called by muse, mutect2, varscan2
- OR6F1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1213416669, COSV100129537; called by muse, mutect2
- OR9K2 | c.922T>A p.L308M (on ENST00000305377; = p.L286M on NM_001005243.1) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100543910; called by muse, mutect2, varscan2
- ORM2 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV99407705; called by muse, mutect2, varscan2
- OSCP1 | c.881A>T p.E294V (on ENST00000356637 / NM_001330493.1; = p.E284V on NM_145047.5) | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99347690; called by muse, mutect2, varscan2
- PAH | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.763); catalogued as COSV100188535; called by muse, mutect2, varscan2
- PAN2 | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs747687739, COSV99228586; called by muse, mutect2
- PAPOLB | c.241A>T p.S81C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101271658; called by muse, mutect2
- PAPPA | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100075786; called by muse, mutect2, varscan2
- PARD3 | c.3458G>T p.R1153L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100632344, COSV100633664; called by muse, mutect2, varscan2
- PAX4 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100490410, COSV58388205; called by muse, mutect2, varscan2
- PCDH10 | c.2842G>T p.G948C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99994841; called by muse, mutect2, varscan2
- PCDH15 | c.3598T>C p.Y1200H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as COSV100229884; called by muse, mutect2, varscan2
- PDE11A | c.1472C>A p.A491D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99615951; called by muse, mutect2, varscan2
- PDYN | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774175877, COSV54101517, COSV54102525; called by muse, mutect2, varscan2
- PEBP4 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99835687; called by muse, mutect2, varscan2
- PLCH1 | c.2282C>A p.P761H (on ENST00000340059 / NM_001130960.2; = p.P773H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100398621; called by muse, mutect2, varscan2
- PLOD1 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV52147272, COSV99539318; called by muse, mutect2
- PLXNC1 | c.3082C>A p.P1028T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99314164; called by muse, mutect2
- PNKD | c.985-2A>G p.X329_splice | Splice Site (SNP) | VAF 60/385 reads (16%) | catalogued as rs766885440, COSV51230888; called by muse, mutect2, varscan2
- POM121C | c.932A>C p.D311A (on ENST00000607367; = p.D69A on NM_001099415.3) | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV99993207; called by muse, mutect2, varscan2
- POPDC3 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634140; called by muse, mutect2, varscan2
- POPDC3 | c.635G>T p.W212L | Missense Mutation (SNP) | VAF 81/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634144; called by muse, mutect2, varscan2
- PRAG1 | c.3814G>C p.E1272Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs779317691, COSV100423010, COSV58159179; called by muse, mutect2, varscan2
- PREX2 | c.1733T>G p.L578R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1465147644, COSV99910717; called by muse, varscan2
- PSKH2 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99405466; called by muse, mutect2, varscan2
- PTPRZ1 | c.5188-1G>T p.X1730_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV101100987; called by muse, mutect2, varscan2
- PTPRZ1 | c.5188G>C p.E1730Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs777963588, COSV101100988; called by muse, mutect2, varscan2
- RELN | c.5018G>T p.S1673I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100635222; called by muse, mutect2, varscan2
- RELN | c.2142C>A p.S714R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as COSV100635223; called by mutect2, varscan2
- RGS21 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314109; called by muse, mutect2, varscan2
- RIN3 | c.1649A>G p.Y550C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV53652893; called by muse, mutect2, varscan2
- RNF113A | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as COSV101007139; called by muse, mutect2, varscan2
- RP1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99609326; called by muse, mutect2, varscan2
- RPAP2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101532193; called by muse, mutect2, varscan2
- RTN1 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); catalogued as COSV50718809, COSV99957242; called by muse, mutect2, varscan2
- RUNX3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV100137180; called by muse, mutect2, varscan2
- RYR1 | c.10892C>A p.A3631E | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100617388; called by muse, mutect2, varscan2
- RYR2 | c.4534G>T p.D1512Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773447; called by muse, mutect2, varscan2
- S1PR4 | c.925T>G p.F309V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV99859524; called by muse, mutect2, varscan2
- SATL1 | c.762G>T p.M254I (on ENST00000395409; = p.M441I on NM_001012980.2) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.292); catalogued as COSV100261169, COSV60578423; called by muse, mutect2, varscan2
- SCN11A | c.4891del p.E1631Kfs*38 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | catalogued as COSV56569596; called by mutect2, pindel, varscan2
- SCN1A | c.3288T>G p.I1096M (on ENST00000303395 / NM_001202435.3; = p.I1085M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.958); catalogued as COSV100322696; called by muse, mutect2, varscan2
- SCP2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as COSV101027313; called by muse, mutect2
- SDK1 | c.5701+1G>A p.X1901_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | catalogued as COSV67364409; called by muse, mutect2, varscan2
- SFXN2 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV100882786; called by mutect2, varscan2
- SH3RF1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99499334, COSV99499669; called by muse, mutect2, varscan2
- SHROOM4 | c.3005A>G p.H1002R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs782443530, COSV99175035; called by muse, mutect2, varscan2
- SIGLEC9 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51583155, COSV51585753; called by muse, mutect2
- SLC22A4 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99569529; called by muse, mutect2, varscan2
- SLC5A12 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV54824039, COSV99745696; called by muse, mutect2, varscan2
- SLC6A3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99549036; called by muse, mutect2, varscan2
- SMG5 | c.3039G>C p.K1013N | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767406504, COSV99431745; called by muse, mutect2, varscan2
- SRSF2 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100334368; called by muse, mutect2, varscan2
- STAT1 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100738982; called by muse, mutect2, varscan2
- STAU2 | c.304G>T p.G102W (on ENST00000524300 / NM_001164380.2; = p.G70W on NM_014393.2) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100869356; called by muse, mutect2, varscan2
- SULT1B1 | c.734C>A p.P245Q | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100150533; called by muse, mutect2
- SULT1C2 | c.358T>C p.W120R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99265522; called by muse, mutect2, varscan2
- SYCP2 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV62773018; called by muse, mutect2, varscan2
- SYNE1 | c.15124G>T p.E5042* (on ENST00000367255 / NM_182961.4; = p.E4971* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99584697; called by muse, mutect2, varscan2
- SYNE1 | c.8883A>T p.Q2961H (on ENST00000367255 / NM_182961.4; = p.Q2968H on NM_033071.3) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.898); catalogued as COSV99584704; called by muse, mutect2, varscan2
- SYNGAP1 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.168); catalogued as COSV99539277; called by muse, mutect2, varscan2
- SYT6 | c.1403G>T p.G468V (on ENST00000610222 / NM_001366225.1; = p.G383V on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101059817, COSV65772759; called by muse, mutect2, varscan2
- TAF1 | c.4586A>T p.D1529V (on ENST00000373790 / NM_138923.4; = p.D1550V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337476; called by muse, mutect2, varscan2
- TAOK1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | catalogued as COSV55589782; called by muse, mutect2, varscan2
- TBCK | c.1868C>G p.A623G (on ENST00000273980 / NM_001163436.4; = p.A560G on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99913376; called by muse, mutect2, varscan2
- TBX10 | c.772T>A p.W258R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100039990; called by muse, mutect2, varscan2
- TCL1A | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1357017975, COSV68086063; called by muse, mutect2, varscan2
- TDRKH | c.1040G>T p.S347I | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100918059; called by muse, mutect2, varscan2
- TGFB1I1 | c.1373A>T p.K458M (on ENST00000394863 / NM_001042454.3; = p.K441M on NM_015927.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100691290; called by muse, mutect2, varscan2
- TIAM2 | c.4863C>G p.F1621L (on ENST00000529824; = p.F1592L on NM_012454.3) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.175); catalogued as COSV99266135; called by muse, mutect2, varscan2
- TMEM120A | c.801G>C p.W267C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781935263, COSV100115807; called by muse, mutect2
- TMEM250 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.021); catalogued as COSV101403448; called by muse, mutect2, varscan2
- TNXB | c.4850C>A p.P1617H (on ENST00000647633; = p.P1370H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100926802; called by muse, mutect2, varscan2
- TRHDE | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99673258; called by muse, mutect2, varscan2
- TRPA1 | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV100085579; called by muse, mutect2, varscan2
- TTN | c.36467C>A p.P12156Q (on ENST00000591111; = p.P4732Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | PolyPhen probably damaging (0.976); catalogued as COSV100636209; called by muse, mutect2
- TTN | c.6208G>T p.E2070* (on ENST00000591111; = p.E2024* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100636213; called by muse, mutect2, varscan2
- TUT4 | c.3232-1G>T p.X1078_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99932998; called by muse, mutect2, varscan2
- TUT4 | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57119139; called by muse, mutect2, varscan2
- TXLNA | c.1374G>T p.E458D | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV101009959; called by muse, mutect2, varscan2
- USP12 | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99997918; called by muse, mutect2, varscan2
- USP46 | c.761A>C p.H254P | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101484331; called by muse, mutect2, varscan2
- UTP20 | c.3668A>G p.K1223R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99882825; called by mutect2, varscan2
- WWP2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.19); catalogued as rs759693369, COSV100598866; called by muse, mutect2
- ZBTB45 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99564717; called by muse, mutect2, varscan2
- ZBTB7B | c.1139G>T p.G380V (on ENST00000292176; = p.G414V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99421722; called by muse, mutect2, varscan2
- ZC3H14 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV51769918, COSV51774439, COSV99193345; called by muse, mutect2, varscan2
- ZKSCAN2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100048662; called by muse, mutect2, varscan2
- ZMAT3 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs151132491, COSV100265451; called by muse, mutect2
- ZNF222 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs368459134; called by muse, mutect2, varscan2
- ZNF283 | c.1788G>C p.E596D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100191170, COSV61030718; called by muse, mutect2, varscan2
- ZNF32 | c.697A>T p.I233F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100986528; called by muse, mutect2, varscan2
- ZNF33A | c.1739A>G p.Y580C (on ENST00000458705 / NM_006974.3; = p.Y581C on NM_006954.2) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1236556395, COSV100276323; called by muse, mutect2, varscan2
- ZNF343 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53853253, COSV99601747; called by muse, mutect2, varscan2
- ZNF431 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.162); catalogued as rs758118322, COSV100219201; called by muse, mutect2
- ZNF439 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100397637; called by muse, mutect2, varscan2
- ZNF521 | c.2830G>T p.G944C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100833666; called by muse, mutect2, varscan2
- ZNF711 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV99341784; called by muse, mutect2, varscan2
- ZNF99 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101234008; called by muse, mutect2
- ADAM20 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAM23 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CFAP44 | c.801del p.T268Qfs*47 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by mutect2, varscan2
- FES | c.150_158del p.H50_L53delinsQ | In Frame Del (DEL) | VAF 23/130 reads (18%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV3D-20 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ITIH2 | c.2082dup p.H695Tfs*6 | Frame Shift Ins (INS) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.221); called by muse, mutect2
- MBD5 | c.872dup p.M291Ifs*6 | Frame Shift Ins (INS) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- RXFP3 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRGC2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 34/241 reads (14%) | called by muse, mutect2, varscan2
- ZDBF2 | c.5893del p.E1965Kfs*36 | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- ABCA3 | c.1821C>T p.S607= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs531041540, COSV100069280; called by muse, mutect2, varscan2
- ADGRL3 | c.2829C>A p.L943= (on ENST00000506720 / NM_001322402.2; = p.L875= on NM_015236.6) | Silent (SNP) | VAF 57/272 reads (21%) | catalogued as COSV101547457; called by muse, mutect2, varscan2
- ALPK2 | c.4671G>T p.T1557= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100864957, COSV64491330; called by muse, mutect2, varscan2
- BCAN | c.1644G>A p.E548= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100228601; called by muse, mutect2, varscan2
- CCDC157 | c.2169C>T p.P723= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99306773; called by muse, varscan2
- CD200R1L | c.426G>A p.V142= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV101236673; called by muse, mutect2, varscan2
- CDCA5 | c.153G>A p.A51= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs751227653, COSV99298107; called by muse, mutect2, varscan2
- CLCN1 | c.2211C>A p.A737= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV58370452; called by muse, mutect2
- CLEC10A | c.466C>T p.L156= (on ENST00000254868 / NM_182906.4; = p.L129= on NM_006344.4) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99645019; called by muse, mutect2, varscan2
- CLRN2 | c.540G>T p.V180= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101492703; called by muse, mutect2, varscan2
- COLGALT1 | c.591G>T p.A197= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99395351; called by muse, mutect2, varscan2
- CYLC2 | c.186T>C p.I62= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100872643; called by muse, mutect2, varscan2
- DIP2B | c.1752A>T p.V584= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV99999728; called by muse, varscan2
- DISP2 | c.2964C>T p.L988= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99140777; called by muse, mutect2, varscan2
- DOCK10 | c.5475A>G p.R1825= | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV99292397; called by muse, mutect2, varscan2
- DPAGT1 | c.231C>G p.P77= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs1029581691, COSV100830803; called by muse, mutect2, varscan2
- DUSP16 | c.888G>A p.K296= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99963466; called by muse, mutect2, varscan2
- DZANK1 | c.1557C>T p.H519= (on ENST00000262547 / NM_001099407.1; = p.H326= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs764179560, COSV99363644; called by muse, mutect2, varscan2
- EBF3 | c.27G>T p.P9= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100799775, COSV62482465; called by muse, mutect2, varscan2
- EPPK1 | c.867G>T p.G289= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101599996; called by muse, mutect2, varscan2
- FGF14 | c.552G>T p.G184= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs1204741145, COSV65953373; called by muse, mutect2, varscan2
- FRY | c.3831C>T p.S1277= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs776063482, COSV100970070; called by muse, mutect2, varscan2
- GCKR | c.1029C>A p.I343= | Silent (SNP) | VAF 53/311 reads (17%) | catalogued as COSV99269572; called by muse, mutect2, varscan2
- GRM5 | c.1836C>G p.S612= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100555112, COSV59595342; called by muse, mutect2, varscan2
- HSP90AA1 | c.1764G>A p.V588= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99355593; called by muse, mutect2, varscan2
- KDM2A | c.9C>G p.P3= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV101284676, COSV101284696; called by muse, mutect2, varscan2
- KIF2B | c.789C>G p.T263= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99276521; called by muse, mutect2, varscan2
- KLK4 | c.489C>T p.T163= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as rs748990839, COSV100133744; called by muse, mutect2, varscan2
- KRT26 | c.639C>A p.T213= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV100156647; called by muse, mutect2
- LMOD1 | c.483C>A p.G161= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100939309; called by muse, mutect2, varscan2
- MGAT5B | c.912G>C p.R304= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs1256094287, COSV100049131; called by muse, mutect2, varscan2
- MUC16 | c.24783A>G p.E8261= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV101202321, COSV67456553; called by muse, mutect2, varscan2
- MUC16 | c.12813C>A p.A4271= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV101202322; called by muse, mutect2, varscan2
- NLGN4X | c.9G>T p.R3= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99324681; called by muse, mutect2, varscan2
- OLFM3 | c.54C>A p.I18= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100130291; called by muse, mutect2
- OR2G3 | c.900T>A p.A300= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV100180851; called by muse, mutect2, varscan2
- OR2T2 | c.264C>G p.S88= | Silent (SNP) | VAF 28/368 reads (8%) | catalogued as COSV100737838; called by muse, mutect2
- OR4E2 | c.513C>A p.P171= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV100330181, COSV57731914; called by muse, mutect2, varscan2
- OR51L1 | c.336G>T p.L112= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV100386521; called by muse, mutect2, varscan2
- OR5J2 | c.174C>G p.P58= | Silent (SNP) | VAF 54/373 reads (14%) | catalogued as COSV100399334, COSV56621442; called by muse, mutect2, varscan2
- OR8B3 | c.180C>T p.Y60= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs1258879613, COSV100660425; called by muse, mutect2, varscan2
- OR9G4 | c.696A>T p.S232= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV100265306; called by muse, mutect2, varscan2
- PI15 | c.732G>T p.L244= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99477701, COSV99478295; called by muse, mutect2, varscan2
- PIK3CG | c.1815C>G p.A605= | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as COSV100783315; called by muse, mutect2, varscan2
- PRTG | c.1707C>A p.L569= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV101221543; called by muse, mutect2, varscan2
- RXFP3 | c.693C>G p.P231= | Silent (SNP) | VAF 2/16 reads (13%) | catalogued as COSV100347893; called by muse, mutect2
- SCN1A | c.1263G>T p.V421= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV100322699; called by muse, mutect2, varscan2
- SI | c.1002A>T p.V334= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100017620; called by muse, mutect2
- SMARCA4 | c.327G>T p.P109= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100759135, COSV100759402, COSV60804992; called by muse, varscan2
- SRRM4 | c.591C>A p.S197= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99939783; called by muse, mutect2, varscan2
- TACC2 | c.2382G>A p.T794= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs746247635, COSV100552091, COSV100554501; called by muse, mutect2, varscan2
- TKFC | c.819A>G p.S273= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1489602105, COSV101204240; called by muse, mutect2, varscan2
- TMPRSS15 | c.2658G>A p.V886= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs368010116; called by muse, varscan2
- TNN | c.1888C>A p.R630= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as COSV53426557; called by muse, mutect2, varscan2
- TNS3 | c.555C>G p.L185= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100236044, COSV100236789; called by muse, mutect2, varscan2
- TRGC2 | c.171C>G p.S57= | Silent (SNP) | VAF 33/243 reads (14%) | called by muse, mutect2, varscan2
- TSPAN11 | c.405G>A p.G135= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1348401079, COSV53819609, COSV99667290; called by muse, mutect2, varscan2
- TTN | c.12390G>A p.S4130= (on ENST00000591111; = p.S4084= on NM_003319.4) | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs755706898, COSV100636212; called by muse, mutect2, varscan2
- TUBB4A | c.826C>A p.R276= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99900239; called by muse, mutect2, varscan2
- UNC13C | c.1992T>A p.A664= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV99524680; called by muse, mutect2, varscan2
- WDR17 | c.3399A>T p.I1133= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99706898, COSV99708522; called by muse, mutect2, varscan2
- ZC3H7A | c.756G>A p.E252= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100865629; called by muse, mutect2
- ZEB1 | c.186A>G p.P62= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100315374; called by muse, mutect2, varscan2
- ZEB1 | c.2394C>T p.N798= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV100315377; called by muse, mutect2, varscan2
- ZFHX4 | c.10575C>A p.S3525= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99269404; called by muse, mutect2, varscan2
- IGKV1-13 | n.284C>G | RNA (SNP) | VAF 30/327 reads (9%) | catalogued as rs1201462788; called by muse, varscan2
- PDZRN4 | c.844-68458G>T | Intron (SNP) | VAF 46/210 reads (22%) | catalogued as COSV54211621; called by muse, mutect2, varscan2
- TBX1 | c.1009+679G>T | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as rs772860144, COSV100226656; called by muse, mutect2, varscan2
- ZNF180 | c.-2C>G | 5'UTR (SNP) | VAF 31/182 reads (17%) | catalogued as COSV55421026; called by muse, mutect2, varscan2
